Somatic mutation profile of tumor specimen TCGA-AK-3427-01A (aliquot TCGA-AK-3427-01A-01W-0886-08) from TCGA case TCGA-AK-3427, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: GX; Age at diagnosis: 65.9 years (24,067 days).
Specimen TCGA-AK-3427-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eb16261a-e037-4fff-9351-98e30faafcce.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AK-3427-10A (Blood Derived Normal), aliquot TCGA-AK-3427-10A-01D-0966-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/498eb430-786e-4c52-80ca-653aef480084

The open-access MAF lists 23 somatic variants for this specimen: 16 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 10, Silent 7, Frame Shift Ins 4, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HPSE2 | c.57dup p.A20Rfs*45 | Frame Shift Ins (INS) | VAF 14/82 reads (17%) | catalogued as rs778121647; ClinVar: pathogenic; called by mutect2, varscan2
- AUTS2 | c.3465G>T p.L1155F | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV61426855; called by muse, varscan2
- CD300LG | c.651dup p.M218Hfs*21 | Frame Shift Ins (INS) | VAF 13/118 reads (11%) | catalogued as rs760923345; called by mutect2, varscan2
- CKAP2L | c.193_195del p.V65del | In Frame Del (DEL) | VAF 63/245 reads (26%) | catalogued as rs1321354894; called by pindel, varscan2
- CYLD | c.2392G>T p.E798* | Nonsense Mutation (SNP) | VAF 20/422 reads (5%) | catalogued as COSV61097103; called by muse, mutect2
- FBXL3 | c.932C>T p.T311I | Missense Mutation (SNP) | VAF 5/126 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62919286; called by muse, mutect2
- FGD6 | c.2731C>A p.P911T | Missense Mutation (SNP) | VAF 88/198 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV59696696; called by muse, mutect2, varscan2
- IL1RL2 | c.1242G>C p.E414D | Missense Mutation (SNP) | VAF 104/274 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51815432, COSV51818378; called by muse, mutect2, varscan2
- LAMB1 | c.3266C>G p.A1089G | Missense Mutation (SNP) | VAF 77/139 reads (55%) | SIFT tolerated (0.37); PolyPhen benign (0.062); catalogued as COSV55969608; called by muse, mutect2, varscan2
- MAPRE3 | c.543dup p.C182Lfs*16 | Frame Shift Ins (INS) | VAF 29/152 reads (19%) | catalogued as rs777328830; called by mutect2, varscan2
- MUC17 | c.11538G>T p.L3846F | Missense Mutation (SNP) | VAF 37/151 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV60301274; called by muse, mutect2, varscan2
- PTEN | c.1011T>A p.F337L | Missense Mutation (SNP) | VAF 18/179 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV64305197; called by muse, mutect2
- RUBCN | c.830dup p.V278Sfs*16 | Frame Shift Ins (INS) | VAF 14/112 reads (13%) | catalogued as rs745498865; called by mutect2, varscan2
- SFRP2 | c.883T>G p.C295G | Missense Mutation (SNP) | VAF 56/167 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56838510; called by muse, mutect2, varscan2
- SLC22A6 | c.1495G>A p.A499T | Missense Mutation (SNP) | VAF 63/162 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as rs565938595, COSV64560550; called by muse, mutect2, varscan2
- ZNF12 | c.1017C>A p.H339Q (on ENST00000405858 / NM_016265.4; = p.H301Q on NM_006956.3) | Missense Mutation (SNP) | VAF 45/199 reads (23%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.997); catalogued as COSV61245469; called by muse, mutect2, varscan2
- ADAR | c.2424C>T p.T808= | Silent (SNP) | VAF 8/150 reads (5%) | catalogued as COSV52720257; called by muse, mutect2
- CAPN10 | c.1047C>A p.G349= | Silent (SNP) | VAF 28/68 reads (41%) | catalogued as COSV54379474; called by muse, mutect2, varscan2
- FLRT2 | c.838C>A p.R280= | Silent (SNP) | VAF 255/438 reads (58%) | catalogued as COSV58149138; called by muse, mutect2, varscan2
- STON2 | c.1992G>T p.G664= (on ENST00000649389 / NM_001366849.2; = p.G607= on NM_001256430.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/243 reads (8%) | catalogued as rs771425761, COSV50853125; called by muse, mutect2
- SYNJ2BP | c.84C>T p.V28= | Silent (SNP) | VAF 23/81 reads (28%) | catalogued as rs763161550, COSV56445467, COSV99832629; called by muse, mutect2, varscan2
- SYNRG | c.3903C>A p.V1301= | Silent (SNP) | VAF 50/841 reads (6%) | called by muse, mutect2
- TRNT1 | c.81A>T p.L27= | Silent (SNP) | VAF 63/180 reads (35%) | catalogued as COSV52409391; called by muse, mutect2, varscan2
